Somatic mutation profile of tumor specimen MP2PRT-PAPFTI-TBP1-A (aliquot MP2PRT-PAPFTI-TBP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPFTI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (609 days).
Specimen MP2PRT-PAPFTI-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3349a936-fdc8-4be3-9ec0-7cbfdc2fa65e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPFTI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPFTI-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ae447bf-3a81-47dd-a492-1612b7a35f9c

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 106/308 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HNF1B | c.1001C>A p.S334Y | Missense Mutation (SNP) | VAF 55/454 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs776928989; called by muse, mutect2, varscan2
- JAKMIP1 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 154/412 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1256164562, COSV51535972; called by muse, mutect2, varscan2
- KLK14 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs373793602; called by muse, mutect2, varscan2
- NWD1 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.267); catalogued as rs778376303, COSV60341091; called by muse, mutect2, varscan2
- CBLL2 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 106/369 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- GSDMC | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.945); called by muse, mutect2
- IGKV2-30 | chr2:89244780 del GAGGCCA | Missense Mutation (DEL) | VAF 24/43 reads (56%) | called by pindel, varscan2
- KIAA0825 | c.1377G>T p.M459I | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- L3MBTL1 | c.2319G>T p.W773C (on ENST00000418998 / NM_001377303.1; = p.W683C on NM_015478.7) | Missense Mutation (SNP) | VAF 17/316 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VMA21 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 98/323 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HCN4 | c.1632G>A p.P544= | Silent (SNP) | VAF 100/212 reads (47%) | catalogued as rs544585089; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP1B | c.2235G>A p.S745= | Silent (SNP) | VAF 75/205 reads (37%) | catalogued as rs149353509; called by muse, mutect2, varscan2
- MYF6 | c.162C>T p.S54= | Silent (SNP) | VAF 18/482 reads (4%) | catalogued as rs1224191607, COSV99952833; called by muse, mutect2
- VGLL1 | c.457C>A p.R153= | Silent (SNP) | VAF 142/405 reads (35%) | called by muse, mutect2, varscan2
